Somatic mutation profile of tumor specimen MMRF_1485_1_BM_CD138pos (aliquot MMRF_1485_1_BM_CD138pos_T2_KAS5U_L02367) from MMRF case MMRF_1485, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.2 years (29,277 days).
Specimen MMRF_1485_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c88c6de-1225-49fc-9882-4e9c74cf91a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1485_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1485_1_PB_Whole_C3_KAS5U_L02375; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f3bbc73-ae34-4574-9c6f-0c7651a374b6

The open-access MAF lists 155 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, 3'UTR 41, Silent 19, Intron 13, 5'UTR 6, 3'Flank 3, Nonsense Mutation 3, Splice Region 2, RNA 2, Frame Shift Del 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 26/169 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 35/168 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF11 | c.4141A>C p.M1381L | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs764914556; called by muse, mutect2, varscan2
- CCDC172 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100319723, COSV60937783; called by muse, mutect2, varscan2
- CD209 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52652317; called by muse, mutect2, varscan2
- CFAP65 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs150834784; called by muse, mutect2, varscan2
- ESR2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs765586360; called by muse, mutect2, varscan2
- GRIN2B | c.3689C>T p.T1230M | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1263518250, COSV101663035; called by muse, mutect2, varscan2
- HGH1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 91/171 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556816512; called by muse, mutect2, varscan2
- HNRNPM | c.2021A>G p.N674S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.996); catalogued as rs764030351, COSV55312229; called by muse, mutect2, varscan2
- IFT57 | c.964C>G p.Q322E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs764185045; called by muse, mutect2, varscan2
- IGHV2-70 | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557960455; called by muse, varscan2
- IGHV2-70 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370713802; called by muse, varscan2
- IGLV2-23 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/18 reads (83%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.488); catalogued as rs756104999; called by muse, varscan2
- IGLV4-60 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs536416304; called by muse, mutect2, varscan2
- IGLV4-60 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs78099525; called by muse, mutect2, varscan2
- IGLV4-60 | c.271A>G p.S91G | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1162635566; called by muse, mutect2, varscan2
- MTUS1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs905903746; called by muse, mutect2, varscan2
- NLRP4 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100016657; called by muse, mutect2, varscan2
- NPBWR1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.92); catalogued as COSV100488060; called by muse, mutect2, varscan2
- NPHS1 | c.3387G>A p.T1129= | Splice Region (SNP) | VAF 26/91 reads (29%) | catalogued as rs780661566; called by muse, mutect2, varscan2
- OR56A4 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1464376555; called by muse, mutect2, varscan2
- PGLYRP2 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs767730436, COSV99484364; called by muse, mutect2, varscan2
- PPFIA4 | c.2885G>A p.R962H (on ENST00000447715; = p.R963H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs767156964; called by muse, mutect2, varscan2
- RNF123 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199544911; called by mutect2, varscan2
- RUNX1T1 | c.239C>G p.T80R (on ENST00000265814 / NM_001198628.1; = p.T53R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.43); PolyPhen benign (0.235); catalogued as rs758568072, COSV56151071, COSV56153017; called by muse, mutect2, varscan2
- SI | c.1713G>A p.E571= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as COSV52296345; called by muse, mutect2, varscan2
- SORCS1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1174198077; called by muse, mutect2, varscan2
- SPECC1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs867992593; called by muse, mutect2, varscan2
- TRAF1 | c.1209C>G p.D403E | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.224); catalogued as rs138123440; called by muse, mutect2, varscan2
- ZNF563 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 28/228 reads (12%) | catalogued as rs755560481, COSV53369897; called by muse, mutect2, varscan2
- ZNF776 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs1198217501; called by muse, mutect2, varscan2
- ADAMTS20 | c.1286T>G p.V429G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHCYL2 | c.1120_1121del p.C374Pfs*2 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.2162-1G>A p.X721_splice | Splice Site (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- ASXL3 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BCL9L | c.872T>A p.L291Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CACNA2D3 | c.1059C>A p.N353K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CC2D1B | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHD1 | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DNAH5 | c.7478G>A p.G2493E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH9 | c.8784G>T p.Q2928H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DOCK2 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSG1 | c.2197G>C p.V733L | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- DUSP2 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2
- ELOA | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM184B | c.3095C>G p.P1032R | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HOMER2 | c.951C>G p.Y317* (on ENST00000304231 / NM_199330.3; = p.Y306* on NM_004839.4) | Nonsense Mutation (SNP) | VAF 91/160 reads (57%) | called by muse, mutect2, varscan2
- IGHA1 | c.100del p.Q34Rfs*6 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- IGLV3-25 | c.74A>C p.Q25P | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- INTS13 | c.1149_1150dup p.I384Rfs*14 | Frame Shift Ins (INS) | VAF 32/183 reads (17%) | called by mutect2, pindel, varscan2
- LHFPL3 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC53 | c.2238G>T p.L746F | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LRRCC1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NBAS | c.2561A>C p.E854A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NKD2 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDHGA7 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RICTOR | c.4917T>G p.I1639M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNASET2 | c.185G>C p.W62S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPSA | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2
- RREB1 | c.4451G>C p.R1484T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SERINC1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SRRM5 | c.1357A>T p.R453* | Nonsense Mutation (SNP) | VAF 72/236 reads (31%) | called by muse, mutect2, varscan2
- TEAD4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TICRR | c.790A>C p.I264L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TIE1 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF251 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF385D | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANHX | c.174C>T p.N58= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs770076790; called by muse, mutect2, varscan2
- BCAM | c.696C>T p.D232= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs375880647; called by muse, mutect2, varscan2
- BPIFB4 | c.1149G>T p.L383= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs923242407; called by muse, varscan2
- CCDC180 | c.1875G>A p.K625= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs1158016256; called by muse, mutect2, varscan2
- CELA2A | c.18G>A p.L6= | Silent (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- CNTLN | c.2226G>A p.E742= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1264123141; called by muse, mutect2, varscan2
- IGLV1-47 | c.174G>A p.Q58= | Silent (SNP) | VAF 102/205 reads (50%) | catalogued as rs181189805; called by muse, varscan2
- IGLV9-49 | c.153A>G p.K51= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs745407211; called by muse, mutect2, varscan2
- KLRF1 | c.510C>T p.Y170= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs370404125; called by muse, mutect2, varscan2
- LNX1 | c.963A>G p.G321= (on ENST00000263925 / NM_001126328.3; = p.G225= on NM_032622.2) | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- OR4K5 | c.606T>C p.N202= | Silent (SNP) | VAF 150/296 reads (51%) | catalogued as rs1434332889; called by muse, mutect2, varscan2
- PMFBP1 | c.2262C>T p.L754= (on ENST00000537465; = p.L749= on NM_031293.3) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs373552286; called by muse, mutect2, varscan2
- RGS22 | c.2403C>T p.Y801= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- SHANK1 | c.588G>A p.A196= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs778366247, COSV99520554; called by muse, mutect2, varscan2
- SLC18A3 | c.1104C>A p.G368= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs1280312684, COSV60326135; called by muse, mutect2, varscan2
- TMC2 | c.2265C>T p.L755= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs555212967, COSV100727732; called by muse, mutect2, varscan2
- TTN | c.100986G>A p.L33662= (on ENST00000591111; = p.L26238= on NM_003319.4) | Silent (SNP) | VAF 95/194 reads (49%) | catalogued as COSV100601594; called by muse, mutect2, varscan2
- WDR87 | c.6330G>A p.R2110= | Silent (SNP) | VAF 113/401 reads (28%) | called by muse, mutect2, varscan2
- ZNF184 | c.172T>C p.L58= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as rs758552695; called by muse, mutect2, varscan2
- AC011294.1 | n.1222T>G | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- ADGRB2 | c.*85G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs568512312; called by muse, mutect2, varscan2
- AFDN | c.5236+103G>C | Intron (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- AL356585.2 | n.712C>A | RNA (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*678C>A | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.-75T>C | 5'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- BCL11B | c.*1770G>A | 3'UTR (SNP) | VAF 23/50 reads (46%) | catalogued as rs1055941310; called by muse, mutect2, varscan2
- BEND4 | c.*142A>G | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- C10orf90 | c.-53T>A | 5'UTR (SNP) | VAF 82/173 reads (47%) | called by muse, mutect2, varscan2
- C2orf68 | c.*1845T>G | 3'UTR (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- CNTN3 | c.*498A>C | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59741C>T | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs995817123; called by muse, mutect2, varscan2
- CSRNP3 | c.*5947C>T | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- DMRTA1 | c.*618A>T | 3'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- DPYSL5 | c.*3326C>A | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- ELF3 | c.*630C>T | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- GFI1B | c.*173G>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- GMNC | c.*519A>G | 3'UTR (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- GPR42 | c.*415G>T | 3'UTR (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- GRIN2B | c.*1550T>C | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by mutect2, varscan2
- H3C13 | c.*24T>A | 3'UTR (SNP) | VAF 96/287 reads (33%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*625C>T | 3'UTR (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- IGLC3 | c.*95C>T | 3'UTR (SNP) | VAF 22/36 reads (61%) | called by mutect2, varscan2
- IQCA1 | c.*386T>G | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- KCNK17 | c.*140A>G | 3'UTR (SNP) | VAF 15/151 reads (10%) | catalogued as rs1009371893; called by muse, mutect2
- KCTD7 | c.*3392C>T | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- LINC01551 | n.1255-5314A>C | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- MAP4K2 | c.-5G>A | 5'UTR (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- MESP1 | c.*942A>G | 3'UTR (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+3890G>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- MTARC1 | c.*102C>G | 3'UTR (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- MYH3 | c.348+78G>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- NLGN1 | c.*1174T>G | 3'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- NRG3 | chr10:81875309 ins G | 5'Flank (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- PPFIBP2 | chr11:7655431 A>C | 3'Flank (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- PRDM2 | c.*1906A>C | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- PREX2 | c.*2178G>A | 3'UTR (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- PURB | c.*3134T>G | 3'UTR (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- RAB39B | c.*605C>T | 3'UTR (SNP) | VAF 58/64 reads (91%) | called by muse, mutect2, varscan2
- RACK1 | c.110-570G>C | Intron (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- RNASE3 | c.*138A>C | 3'UTR (SNP) | VAF 62/442 reads (14%) | called by muse, mutect2, varscan2
- ROBO2 | c.3554+99G>A | Intron (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- RSF1 | c.*2045C>T | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- SDK1 | c.*3148C>T | 3'UTR (SNP) | VAF 15/111 reads (14%) | catalogued as rs572820239, COSV101269943; called by muse, mutect2, varscan2
- SEMA4D | c.1883-719T>A | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.*791G>A | 3'UTR (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- SFTPA1 | c.-23-108G>A | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as rs913229413; called by muse, mutect2, varscan2
- SHKBP1 | c.320-120C>G | Intron (SNP) | VAF 26/40 reads (65%) | called by muse, mutect2, varscan2
- SKOR2 | c.-14G>T | 5'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837921 T>C | 3'Flank (SNP) | VAF 43/373 reads (12%) | called by muse, mutect2, varscan2
- SLC12A7 | c.*329C>A | 3'UTR (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- SLC6A7 | c.*1243G>T | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- SMARCB1 | chr22:23836310 G>C | 3'Flank (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- SNAI3 | c.76+65A>G | Intron (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- SOAT2 | c.-17C>T | 5'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- SSU72 | c.225-1036G>C | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52216472; called by muse, mutect2, varscan2
- TBX2 | c.-205C>A | 5'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs1183282259; called by muse, mutect2
- TCF20 | c.*195C>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- THAP3 | c.75-50G>T | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- TRIM32 | c.*442A>G | 3'UTR (SNP) | VAF 31/93 reads (33%) | catalogued as rs917981790; called by muse, mutect2, varscan2
- TSPAN5 | c.*583C>T | 3'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as rs373706140; called by muse, mutect2
- TXNDC5 | c.*1389G>A | 3'UTR (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- UBC | chr12:124914922 T>C | 5'Flank (SNP) | VAF 13/37 reads (35%) | catalogued as rs1021338425; called by muse, mutect2, varscan2
- UBXN10 | c.*800A>C | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.*1022A>G | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- ZNF354B | c.*470C>T | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- ZNF792 | c.*1293C>G | 3'UTR (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
